Surgical pathology report (de-identified scan), TCGA case TCGA-N9-A4Q8, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MD Anderson, specimen TCGA-N9-A4Q8-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time:

DIAGNOSIS

(A) UTERUS AND CERVIX, PARAMETRIUM, BOTH TUBES AND OVARIES:

MALIGNANT MIXED MULLERIAN TUMOR (CARCINOSARCOMA) ARISING IN AN ENDOMETRIAL POLYP.
TUMOR EXTENDS TO THE LOWER UTERINE SEGMENT, BUT DOES NOT INVOLVE THE CERVIX.
SUPERFICIAL MYOMETRIAL INVASION (0.5 MM) IS PRESENT (TOTAL MYOMETRIAL THICKNESS IS 12 MM).

No lymphovascular space invasion is identified.

Bilateral parametria are free of tumor.

Vaginal cuff is free of tumor.

Adenomyosis and endometriosis.

Myometrial leiomyoma.

Cervix, no tumor present.

Bilateral fallopian tubes, no tumor present.

Bilateral ovaries, no tumor present.

(B) RIGHT PELVIC LYMPH NODES:

Eleven lymph nodes, no tumor present (0/11).

(C) LEFT PELVIC LYMPH NODES:

Six lymph nodes, no tumor present (0/6).

(D) PARA-AORTIC LYMPH NODES:

Nine lymph nodes, no tumor present (0/9).

(E) OMENTAL BIOPSY:

Adipose tissue, no tumor present.

COMMENT

Blocks A18 and A27 can be used for future molecular diagnostic tests if necessary.

ICD-O-3

Mixed Mullerian tumor 8450/3

Site Path: Endometrium C54.1

CQCP: Uterus NOS C55.9

Copied ASD 1/16/13

GROSS DESCRIPTION

(A) UTERUS AND CERVIX, PARAMETRIUM AND BOTH TUBES AND OVARIES – Consists of a 130 gram specimen including the uterus (9.5 x 5.5 x 3.5 cm) with a portion of vaginal cuff ranging in length from 0.1 to 0.3 cm, bilateral parametria (5.0 x 4.0 x 0.2 cm each side), and bilateral adnexae. The specimen is bivalved to reveal a friable red-yellow mass filling the entire endometrial cavity and extending to the lower uterine segment (4.5 x 4.0 cm) with a thickness of 0.1 cm. Grossly the mass is superficially attached to the myometrium, with no gross evidence of myometrial invasion. The myometrium is pink-tan striated (1.3 cm in thickness). An intramural fibroid on the posterior aspect of the uterus is identified (5.0 x 1.3 x 1.3 cm). The cervical canal is grossly unremarkable and patent.

The left tube (7.8 x 0.3 cm) is grossly unremarkable. The left ovary (1.7 x 1.7 x 0.7 cm) is cerebriform yellow-pink and slightly firm. The inferior adnexal soft tissue from this side is tightly adherent to the cervix.

The right tube (7.5 x 0.3 cm) is grossly unremarkable and patent. The right ovary (1.7 x 1.0 x 0.7 cm) is grossly unremarkable.

INK CODE: Blue – anterior; black – posterior.

SECTION CODE: A1, vaginal cuff from 12-3 o'clock shave; A2, vaginal cuff from 3-6 o'clock shave; A3, vaginal cuff from 6-9 o'clock shave; A4, vaginal cuff from 9-12 o'clock shaved; A5, right parametrium margin shaved; A6, left parametrium margin shaved; A7-A10, right parametrium perpendicularly submitted from superior to inferior; A11-A13, left parametrium perpendicular from superior-to-inferior; A14, A15, left adherent adnexa to cervix; A16, anterior cervix full-thickness; A17, posterior cervix full-thickness; A18, anterior lower uterine segment full-thickness; A19, posterior lower uterine segment full-thickness; A20, representative of right tube; A21, right fimbriae; A22, representative right ovary; A23, representative left tube; A24, left fimbriae;

[page 2 of 2]
A25, representative left ovary; A26-A28, representative of anterior uterine tumor full-thickness; A29, A30, representative of posterior uterine tumor full-thickness; A32, representative of posterior endomyometrium full-thickness with fibroid; A33, representative of detached friable tumor.

(B) RIGHT PELVIC LYMPH NODES – The specimen consists of multiple red-yellow fragments of fibroadipose tissue aggregating to 4.5 x 3 x 0.7 cm. Dissection reveals eleven possible lymph nodes ranging in size from 0.1 cm to 3 cm in greatest dimension. All possible lymph nodes are submitted entirely.

SECTION CODE: B1, one possible lymph node; B2, three possible lymph nodes; B3, two possible lymph nodes; B4, two possible lymph nodes; B5, two possible lymph nodes; B6, B7, one possible lymph node, sectioned.

(C) LEFT PELVIC LYMPH NODES – The specimen consists of multiple red-yellow fragments of fibroadipose tissue aggregating to 3.5 x 3 x 0.7 cm. Dissection reveals six possible lymph nodes ranging in size from 1.7 cm to 3.8 cm in greatest dimension. All possible lymph nodes are submitted entirely. The entire specimen is submitted.

SECTION CODE: C1, two possible lymph nodes; C2, two possible lymph nodes; C3, one possible lymph node, bisected; C4, C5, one possible lymph node, bisected; C6, remaining fibroadipose tissue.

(D) PARAAORTIC LYMPH NODE – A 5.5 x 4.0 x 0.8 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal nine possible lymph nodes ranging from 0.4 x 0.3 x 0.2 cm – 6.5 x 0.8 x 0.3 cm.

SECTION CODE: D1, two possible lymph nodes; D2, three possible lymph nodes; D3, one possible lymph node, serially sectioned; D4, one possible lymph node, serially sectioned; D5, D6, one possible lymph node, serially sectioned; D7-D9, one possible lymph node, serially sectioned.

(E) OMENTAL BIOPSY – A 21.0 x 5.0 x 0.8 cm unoriented sheet of finely lobulated adipose tissue. The specimen is sectioned to reveal cut surfaces composed of unremarkable fibroadipose tissue. Nodules or masses are not grossly identified.

SECTION CODE: E1-E5, representative sections.

CLINICAL HISTORY

Uterine cancer

SNOMED CODES

T-83020, M-85903

"Some tests reported here may have been developed and performance characteristics determined specifically cleared or approved by the U.S. Food and Drug Administration."

tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Preliminary: 10/15/12 LW

HIF-VA Discrepancy		X
Reviewed (initials):		

10/15/12

Source: NCI Genomic Data Commons file 8ec66a88-5480-42ec-a4d9-97e867369023 (TCGA-N9-A4Q8.7C192804-4D60-4F00-B932-C4B416A04F58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).